Somatic mutation profile of tumor specimen ALCH-B2BT-TTP1-A (aliquot ALCH-B2BT-TTP1-A-1-0-D-A776-36) from ALCHEMIST case ALCH-B2BT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.2 years (21,266 days).
Specimen ALCH-B2BT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 291e5abd-c3a5-4d85-8430-a48a98317ed0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2BT-NB1-A (Blood Derived Normal), aliquot ALCH-B2BT-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cf479a2-d80a-4958-ae7d-173280e78e24

The open-access MAF lists 273 somatic variants for this specimen: 192 protein-altering or splice-affecting, 50 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 161, Silent 50, Nonsense Mutation 17, Intron 15, RNA 6, Frame Shift Del 6, 3'UTR 5, Splice Site 4, 5'UTR 3, Splice Region 3, 5'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHAMP1 | c.2029G>T p.E677* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as rs863225073, CM165829; ClinVar: likely pathogenic; called by muse, varscan2
- NFE2L2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 6/98 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 28/170 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM5 | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs768006269, COSV100088760; called by mutect2, varscan2
- ACTRT1 | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs750564045, COSV64419460, COSV64420243; called by muse, mutect2
- ADCY1 | c.281C>G p.S94* | Nonsense Mutation (SNP) | VAF 5/67 reads (7%) | catalogued as COSV99811225; called by muse, mutect2
- AL592490.1 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.28); catalogued as rs1267404867; called by muse, mutect2
- AP002512.3 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as rs1239468898; called by muse, mutect2
- AR | c.1616G>T p.R539L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.97); catalogued as COSV65959510; called by muse, mutect2, varscan2
- ATAT1 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 27/240 reads (11%) | catalogued as rs151162327; called by muse, mutect2, varscan2
- ATP9A | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58765042; called by muse, mutect2, varscan2
- AZIN1 | c.34G>T p.V12F | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV61479095; called by muse, mutect2, varscan2
- BPIFB6 | c.1113C>A p.N371K | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as rs763912790; called by muse, mutect2, varscan2
- C7orf57 | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.012); catalogued as COSV62361927; called by muse, mutect2
- CA8 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV58770616; called by muse, mutect2, varscan2
- CCDC89 | c.93C>A p.N31K | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs1432480012; called by muse, mutect2, varscan2
- CDHR3 | c.1318dup p.Y440Lfs*3 | Frame Shift Ins (INS) | VAF 19/129 reads (15%) | catalogued as rs747038914, COSV58414424; called by mutect2, pindel, varscan2
- CLVS1 | c.629A>C p.Q210P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs757350983; called by mutect2, varscan2
- CSMD3 | c.6200G>A p.R2067K (on ENST00000297405 / NM_001363185.1; = p.R1963K on NM_052900.3) | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV52243858, COSV52280475; called by muse, mutect2
- CWH43 | c.1549C>A p.H517N | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as rs556087852; called by muse, mutect2, varscan2
- CYP2J2 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs186560946; called by muse, mutect2, varscan2
- DECR2 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54795856; called by muse, mutect2, varscan2
- DENND1B | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.06); catalogued as rs1186303809; called by muse, mutect2, varscan2
- DSC3 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV64572136; called by muse, mutect2
- DYSF | c.3004G>C p.D1002H | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50587415; called by muse, mutect2
- EHBP1 | c.100A>T p.K34* | Nonsense Mutation (SNP) | VAF 12/120 reads (10%) | catalogued as COSV50420969; called by muse, mutect2, varscan2
- ENPP1 | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 32/357 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV62935046; called by muse, mutect2
- FGFR1 | c.1709G>A p.R570Q (on ENST00000447712 / NM_023110.3; = p.R568Q on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/144 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1399523084, COSV58328321, COSV58344327; called by muse, mutect2, varscan2
- FLI1 | c.893G>C p.S298T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV55644520; called by muse, mutect2, varscan2
- FNBP1 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 16/147 reads (11%) | catalogued as COSV100852696; called by muse, mutect2, varscan2
- FRY | c.6943G>T p.V2315L | Missense Mutation (SNP) | VAF 21/239 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1277964828; called by muse, mutect2
- FYCO1 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV56113776; called by muse, mutect2
- FZD10 | c.1537G>C p.V513L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.268); catalogued as COSV99969450; called by muse, mutect2, varscan2
- GBP1 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 10/130 reads (8%) | catalogued as COSV65084335; called by muse, mutect2
- GON4L | c.766G>C p.G256R | Missense Mutation (SNP) | VAF 77/423 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV55204534; called by muse, mutect2, varscan2
- GREB1L | c.1951G>T p.E651* | Nonsense Mutation (SNP) | VAF 18/111 reads (16%) | catalogued as COSV52548137; called by muse, mutect2, varscan2
- IGDCC3 | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1386257774; called by muse, varscan2
- IL17A | c.228C>A p.L76= | Splice Region (SNP) | VAF 7/67 reads (10%) | catalogued as rs1325520745; called by muse, mutect2
- ITGAL | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.784); catalogued as COSV63321908; called by muse, mutect2
- KHDRBS2 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55451346; called by muse, mutect2
- LHX4 | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.316); catalogued as rs761944467, COSV99761922; called by muse, mutect2, varscan2
- MARCO | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1440750280; called by muse, mutect2, varscan2
- MMP16 | c.671C>G p.S224* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV54188188; called by muse, mutect2
- MYCBP2 | c.13159G>A p.D4387N (on ENST00000357337; = p.D4425N on NM_015057.5) | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs941096147; called by muse, mutect2, varscan2
- MYCBPAP | c.1543C>G p.P515A | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1211213606; called by muse, mutect2, varscan2
- MYO16 | c.4641G>T p.K1547N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs375544176; called by mutect2, varscan2
- NBAS | c.4291G>T p.A1431S | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.354); catalogued as COSV55713091; called by muse, mutect2, varscan2
- NBEA | c.3772G>T p.G1258* | Nonsense Mutation (SNP) | VAF 8/99 reads (8%) | catalogued as COSV100083543; called by muse, mutect2
- NPC1L1 | c.2902C>T p.R968C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs748641132, COSV56930436; called by muse, mutect2, varscan2
- NTHL1 | c.841C>T p.L281F (on ENST00000219066; = p.L273F on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs939350999; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OLFM4 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.339); catalogued as COSV99524338; called by muse, mutect2, varscan2
- OPTC | c.102G>T p.M34I | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100557951; called by muse, mutect2, varscan2
- OR4K13 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV59859697; called by muse, mutect2
- OR6Q1 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as COSV56933230; called by muse, mutect2
- PAN2 | c.3369C>G p.Y1123* (on ENST00000425394 / NM_001127460.3; = p.Y1119* on NM_014871.5) | Nonsense Mutation (SNP) | VAF 18/163 reads (11%) | catalogued as COSV56264622; called by muse, mutect2, varscan2
- PCDHA5 | c.1780C>A p.R594S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.334); catalogued as COSV65351686; called by muse, mutect2
- PLXNA4 | c.756C>A p.N252K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.216); catalogued as COSV58170212; called by muse, mutect2, varscan2
- PMFBP1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as rs770063636, COSV52821228; called by muse, mutect2, varscan2
- PON3 | c.352A>G p.I118V | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1165916552; called by muse, mutect2, varscan2
- PRDM9 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 21/264 reads (8%) | catalogued as COSV99689765; called by muse, mutect2
- PROS1 | c.1573G>T p.A525S | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.514); catalogued as CM961189; called by muse, mutect2, varscan2
- PRSS45P | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as rs778464593, COSV70577427; called by muse, mutect2, varscan2
- R3HDM2 | c.2728G>A p.G910S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs772187681; called by mutect2, varscan2
- RGL4 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.321); catalogued as rs1411239362, COSV51943737; called by muse, mutect2
- RNF145 | c.1874G>T p.G625V (on ENST00000424310 / NM_001199383.2; = p.G653V on NM_144726.2) | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as rs745401448; called by muse, mutect2
- S100A7L2 | c.23A>T p.K8I | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV64194872; called by muse, mutect2
- SEMG2 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); catalogued as COSV65647885; called by muse, mutect2, varscan2
- SIGLEC14 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1308140616, COSV99707805; called by mutect2, varscan2
- SMC6 | c.2365C>G p.Q789E | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as COSV100704851; called by muse, mutect2
- SPATA31E1 | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV57789414, COSV57791962; called by muse, mutect2, varscan2
- SYN1 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765183335, COSV55984996; called by muse, mutect2, varscan2
- TENT5C | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs750335875; called by muse, mutect2
- TEX13A | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs868964493, COSV61150398; called by muse, mutect2, varscan2
- TNK2 | c.2255C>T p.P752L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs769251815; called by muse, varscan2
- TRMT11 | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1288950464; called by muse, mutect2
- TTC25 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as rs782126150, COSV66367545; called by muse, mutect2, varscan2
- TTN | c.35423C>T p.P11808L (on ENST00000591111; = p.P10881L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/147 reads (4%) | PolyPhen probably damaging (0.998); catalogued as COSV60017641; called by muse, mutect2
- TTN | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 30/211 reads (14%) | PolyPhen benign (0.05); catalogued as COSV99045880; called by muse, mutect2, varscan2
- UBR4 | c.5455A>C p.M1819L | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV64400402; called by muse, mutect2, varscan2
- WDR24 | c.1755C>G p.I585M (on ENST00000248142; = p.I455M on NM_032259.4) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as rs770860732; called by muse, mutect2, varscan2
- ZFHX4 | c.950G>T p.C317F | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV50668270; called by muse, mutect2, varscan2
- ZFHX4 | c.8506G>T p.A2836S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as rs754367335, COSV51487306; called by mutect2, varscan2
- ZNF131 | c.1847G>C p.R616T (on ENST00000509156 / NM_001330707.2; = p.R582T on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV100185769; called by muse, mutect2, varscan2
- ZNF479 | c.461A>G p.N154S | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV58644049; called by muse, mutect2, varscan2
- ZNF521 | c.3788C>T p.T1263I | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1446578458; called by muse, mutect2
- ZNF668 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs756378883; called by muse, varscan2
- ADCY5 | c.2049C>A p.H683Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- AGA | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.411); called by muse, mutect2
- AHNAK | c.10975T>A p.F3659I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ANGEL1 | c.41C>T p.T14M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ANK2 | c.4956A>T p.K1652N | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.066); called by muse, mutect2
- AVIL | c.1561G>C p.D521H | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2
- C9orf72 | c.1017del p.W340Gfs*25 | Frame Shift Del (DEL) | VAF 18/142 reads (13%) | called by mutect2, pindel, varscan2
- CCR7 | c.101G>C p.G34A | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.028); called by muse, mutect2
- CDH11 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CFAP61 | c.524A>G p.H175R | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.466); called by muse, mutect2
- CHRNA9 | c.1410G>T p.M470I | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); called by muse, mutect2
- COBL | c.1024C>A p.Q342K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.281); called by muse, mutect2
- COL4A5 | c.3262C>A p.P1088T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.657); called by muse, mutect2
- COPB2 | c.949del p.A317Pfs*11 | Frame Shift Del (DEL) | VAF 34/229 reads (15%) | called by mutect2, pindel, varscan2
- CPB1 | c.1069C>G p.P357A | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.582); called by muse, mutect2
- CRLF1 | c.1215C>A p.D405E | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CWF19L2 | c.92A>T p.E31V | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- CYP4F2 | c.-1-6C>A | Splice Region (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- DCDC1 | c.3845A>T p.K1282M (on ENST00000597505 / NM_001367979.1; = p.K389M on NM_020869.3) | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- DDIT4L | c.467G>T p.S156I | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DDX39B | c.953A>T p.H318L | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DELE1 | c.993G>A p.W331* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | called by muse, mutect2, varscan2
- DHX36 | c.2909A>G p.N970S | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH17 | c.3299A>G p.E1100G | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- DPYSL4 | c.403T>A p.Y135N | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EIF3E | c.713A>T p.Y238F | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FAF1 | c.1766G>T p.R589L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FAM13A | c.1225del p.R409Afs*36 | Frame Shift Del (DEL) | VAF 23/112 reads (21%) | called by mutect2, pindel, varscan2
- FAM189A1 | c.802C>A p.L268M | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, varscan2
- FAR1 | c.769-2A>C p.X257_splice | Splice Site (SNP) | VAF 10/90 reads (11%) | called by muse, varscan2
- FSHB | c.260del p.H87Lfs*41 | Frame Shift Del (DEL) | VAF 16/142 reads (11%) | called by mutect2, varscan2
- GAK | c.3510T>C p.A1170= | Splice Region (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- GAS2L3 | c.1132G>T p.A378S | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- GATA3 | c.179T>A p.V60D | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GIMAP1-GIMAP5 | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.14); called by muse, mutect2
- GPM6A | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GRIA1 | c.1799A>T p.Q600L | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- HOXB2 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- HPS5 | c.1336A>G p.I446V (on ENST00000349215 / NM_181507.2; = p.I332V on NM_007216.4) | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HTT | c.6415-2A>G p.X2139_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- IGSF10 | c.4612A>G p.T1538A | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGSF11 | c.277G>T p.G93* (on ENST00000393775 / NM_001015887.3; = p.G92* on NM_152538.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2, varscan2
- IQGAP3 | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2
- IQSEC1 | c.2723A>G p.D908G | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); called by muse, mutect2
- ITGAD | c.2641G>A p.V881I | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- ITPRID1 | c.2260G>A p.A754T | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.029); called by muse, mutect2
- IVL | c.1081G>T p.G361W | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KIAA1109 | c.5710+1del | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel
- LRP1B | c.2498G>A p.C833Y | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- LRRC2 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- LRRIQ1 | c.3772C>G p.P1258A | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- LTF | c.1666G>T p.E556* | Nonsense Mutation (SNP) | VAF 16/215 reads (7%) | called by muse, mutect2
- MTTP | c.1888A>T p.T630S | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- NAV3 | c.1644C>A p.S548R | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); called by muse, mutect2
- NCOA1 | c.3948C>A p.S1316R | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- NFASC | c.1621C>A p.L541M (on ENST00000339876 / NM_001378329.1; = p.L552M on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by mutect2, varscan2
- NINL | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- NR4A2 | c.1109G>C p.R370T | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- OMD | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2
- OR10A4 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR10A7 | c.439G>C p.G147R | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- OR4M1 | c.688G>T p.G230C | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PACSIN3 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- PAPLN | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PCDHB12 | c.1835C>A p.P612H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- PCDHB8 | c.1887G>T p.R629S | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- PLCB1 | c.916G>C p.V306L | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2
- POLE | c.6184A>C p.S2062R | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- POLH | c.939G>T p.R313S | Missense Mutation (SNP) | VAF 44/368 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAMEF1 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 19/293 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.106); called by muse, mutect2
- PRKAG2 | c.1357G>T p.V453L | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- PRKG1 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- PTPRC | c.1040T>A p.M347K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- RASGRP2 | c.1096-1G>A p.X366_splice | Splice Site (SNP) | VAF 19/186 reads (10%) | called by muse, mutect2, varscan2
- RNF6 | c.757A>T p.T253S | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- RNFT2 | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SAMD12 | c.599A>G p.Q200R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA4D | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.014); called by muse, varscan2
- SIM1 | c.1939G>T p.D647Y | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); called by muse, mutect2
- SLC19A2 | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC6A2 | c.1645A>C p.I549L | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLCO1A2 | c.1793+1del p.X598_splice | Splice Site (DEL) | VAF 8/74 reads (11%) | called by pindel, varscan2
- SP8 | c.41C>T p.P14L (on ENST00000361443 / NM_198956.4; = p.P32L on NM_182700.6) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2
- SPEG | c.9253G>T p.D3085Y | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRPK2 | c.1026T>A p.N342K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE2 | c.12634G>C p.D4212H | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TDRD6 | c.2708T>C p.I903T | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TET2 | c.2138T>G p.F713C | Missense Mutation (SNP) | VAF 51/496 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2
- TFAP2B | c.1301_1304del p.N434Tfs*38 | Frame Shift Del (DEL) | VAF 17/140 reads (12%) | called by mutect2, pindel, varscan2
- TMEM161B | c.1369G>T p.G457* | Nonsense Mutation (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- TMEM207 | c.287A>G p.D96G | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMTC1 | c.1603A>T p.M535L (on ENST00000539277 / NM_001193451.2; = p.M427L on NM_175861.3) | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TNS3 | c.1439A>T p.D480V | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TOGARAM2 | c.790G>T p.G264C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TRIM51GP | c.13A>G p.I5V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2
- TRPM8 | c.1184A>C p.K395T | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2
- USP9X | c.2936C>T p.S979F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR24 | c.1016C>T p.P339L (on ENST00000248142; = p.P209L on NM_032259.4) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- XIRP2 | c.3634G>T p.V1212F (on ENST00000628543; = p.V1387F on NM_152381.6) | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XRCC1 | c.1321C>G p.Q441E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- XRN1 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- ZFHX4 | c.1474A>T p.T492S | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZFHX4 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF165 | c.202A>T p.S68C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- ZNF23 | c.591G>C p.Q197H | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ZNF311 | c.1798G>A p.G600R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ACSS3 | c.1893T>A p.A631= | Silent (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- ADCY10 | c.2043A>G p.A681= | Silent (SNP) | VAF 23/182 reads (13%) | called by muse, mutect2, varscan2
- ANXA2 | c.483G>A p.S161= | Silent (SNP) | VAF 21/164 reads (13%) | catalogued as rs760126181; called by muse, mutect2, varscan2
- ASPM | c.5373G>A p.Q1791= | Silent (SNP) | VAF 26/237 reads (11%) | called by muse, mutect2, varscan2
- ATP10A | c.2238C>A p.R746= | Silent (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- CASR | c.171T>A p.S57= | Silent (SNP) | VAF 13/235 reads (6%) | called by muse, mutect2
- CCDC39 | c.1938T>G p.T646= | Silent (SNP) | VAF 10/219 reads (5%) | catalogued as rs1254154027; called by muse, mutect2
- CCDC39 | c.1125T>C p.T375= | Silent (SNP) | VAF 74/191 reads (39%) | called by muse, mutect2, varscan2
- CCND2 | c.672T>C p.T224= | Silent (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- CDH11 | c.630G>T p.V210= | Silent (SNP) | VAF 17/103 reads (17%) | called by muse, mutect2, varscan2
- CDH22 | c.66G>A p.L22= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1226063577; called by muse, varscan2
- CEP164 | c.3567A>G p.K1189= | Silent (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- COL14A1 | c.2166A>T p.T722= | Silent (SNP) | VAF 27/155 reads (17%) | called by muse, mutect2, varscan2
- CRB1 | c.4104C>T p.V1368= | Silent (SNP) | VAF 20/344 reads (6%) | catalogued as rs781437952; called by muse, mutect2
- DHX16 | c.1485C>T p.Y495= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as rs1302472778, COSV64562876; called by muse, mutect2
- DLG5 | c.4146C>T p.I1382= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs568757709, COSV64947676; called by muse, mutect2, varscan2
- DNAH11 | c.6288A>G p.A2096= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as rs905167931, COSV60943746; called by muse, mutect2, varscan2
- FASN | c.2685G>T p.V895= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV60754319; called by muse, mutect2, varscan2
- FBXW12 | c.1200T>G p.S400= | Silent (SNP) | VAF 10/137 reads (7%) | called by muse, mutect2
- GRIK2 | c.1590C>A p.S530= | Silent (SNP) | VAF 11/144 reads (8%) | catalogued as COSV59711420; called by muse, mutect2
- HTR2A | c.991C>T p.L331= | Silent (SNP) | VAF 30/191 reads (16%) | called by muse, mutect2, varscan2
- IGSF9B | c.1641G>C p.R547= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- IMPG2 | c.330C>A p.V110= | Silent (SNP) | VAF 11/198 reads (6%) | called by muse, mutect2
- ITIH6 | c.2532C>A p.I844= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99513155; called by muse, mutect2, varscan2
- KLHL41 | c.1068T>C p.D356= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs566205759; called by muse, mutect2, varscan2
- KSR2 | c.369G>C p.T123= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV100348296; called by muse, mutect2, varscan2
- LAMC2 | c.3102G>A p.V1034= | Silent (SNP) | VAF 16/362 reads (4%) | called by muse, mutect2
- LRRK1 | c.3558G>A p.Q1186= | Silent (SNP) | VAF 11/116 reads (9%) | catalogued as rs913955477; called by muse, mutect2, varscan2
- NTN4 | c.1770A>G p.A590= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs754682849; called by muse, mutect2, varscan2
- NXF3 | c.1140C>T p.F380= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- PANX2 | c.867C>T p.I289= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, varscan2
- PIK3R6 | c.855C>A p.I285= | Silent (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- PLEC | c.8256C>T p.V2752= (on ENST00000322810 / NM_201380.4; = p.V2642= on NM_000445.5) | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, varscan2
- SLC6A12 | c.771T>C p.G257= | Silent (SNP) | VAF 15/152 reads (10%) | catalogued as rs1302302300; called by muse, mutect2, varscan2
- SVIL | c.4692C>T p.C1564= (on ENST00000355867 / NM_021738.3; = p.C1138= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as rs1342789344; called by muse, mutect2, varscan2
- SYT1 | c.1185G>C p.L395= | Silent (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- TBL3 | c.2316C>T p.S772= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs773322488; called by muse, varscan2
- TGFBRAP1 | c.333T>A p.P111= | Silent (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
- TMPRSS6 | c.2196G>A p.V732= | Silent (SNP) | VAF 12/193 reads (6%) | called by muse, mutect2
- TNR | c.2910G>A p.L970= | Silent (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- TNRC18 | c.4665G>T p.L1555= | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as COSV68165959; called by muse, mutect2, varscan2
- TP53TG5 | c.507C>T p.N169= | Silent (SNP) | VAF 18/204 reads (9%) | called by muse, mutect2
- TRAPPC2B | c.90C>G p.S30= | Silent (SNP) | VAF 42/287 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.24936C>A p.G8312= (on ENST00000591111; = p.G7385= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.630T>C p.T210= | Silent (SNP) | VAF 31/214 reads (14%) | called by muse, mutect2, varscan2
- VPS18 | c.1395G>A p.Q465= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- VWC2 | c.90C>T p.S30= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99080283; called by muse, mutect2, varscan2
- YTHDF3 | c.903C>T p.I301= | Silent (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- ZNF385D | c.132A>T p.A44= | Silent (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- ZNF862 | c.1413G>T p.G471= | Silent (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- AC011294.1 | n.188T>A | RNA (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2, varscan2
- ALB | c.843+38G>T | Intron (SNP) | VAF 38/177 reads (21%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503884 G>A | 5'Flank (SNP) | VAF 4/42 reads (10%) | catalogued as rs1565055273; called by mutect2, varscan2
- ARRDC1 | c.229+128G>C | Intron (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- CFAP126 | c.*1G>T | 3'UTR (SNP) | VAF 16/62 reads (26%) | called by muse, varscan2
- CNTNAP3P2 | n.1028T>C | RNA (SNP) | VAF 10/117 reads (9%) | called by muse, mutect2, varscan2
- COL4A1 | c.4022-48C>G | Intron (SNP) | VAF 6/39 reads (15%) | called by mutect2, varscan2
- CSMD2 | c.1326+5860G>A | Intron (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- DAB2 | c.330+17G>C | Intron (SNP) | VAF 17/213 reads (8%) | called by muse, mutect2
- FSHR | c.374+2565A>T | Intron (SNP) | VAF 19/166 reads (11%) | called by muse, varscan2
- GJA5 | c.-5C>T | 5'UTR (SNP) | VAF 28/165 reads (17%) | catalogued as rs1553227122; called by muse, mutect2, varscan2
- ITGAL | c.62-208C>A | Intron (SNP) | VAF 28/241 reads (12%) | called by muse, varscan2
- KMT5C | c.570+1011G>T | Intron (SNP) | VAF 14/177 reads (8%) | called by muse, mutect2
- MED19 | c.571+91C>G | Intron (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- MYADML | n.625G>A | RNA (SNP) | VAF 5/37 reads (14%) | catalogued as rs765923983; called by muse, mutect2, varscan2
- MYLK2 | c.1083-10G>T | Intron (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- NEB | c.11601+2239C>A | Intron (SNP) | VAF 16/294 reads (5%) | catalogued as rs1382871208; called by muse, mutect2
- NOC2LP2 | n.1743G>T | RNA (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- POLG | c.2157+14C>A | Intron (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- PPA1 | c.512-17G>A | Intron (SNP) | VAF 19/149 reads (13%) | catalogued as rs1348789798; called by muse, mutect2, varscan2
- RBKS | c.796-831G>C | Intron (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- SLC25A19 | c.*40C>T | 3'UTR (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- SNORD93 | n.51G>T | RNA (SNP) | VAF 13/140 reads (9%) | called by muse, mutect2
- TDG | c.-28G>A | 5'UTR (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- TXNL1 | c.*19C>T | 3'UTR (SNP) | VAF 25/162 reads (15%) | called by muse, mutect2, varscan2
- UMPS | c.*1333T>G | 3'UTR (SNP) | VAF 5/45 reads (11%) | catalogued as rs1339329329; called by muse, varscan2
- VAPB | c.*844G>A | 3'UTR (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- WRAP53 | c.1164+29C>T | Intron (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2, varscan2
- WT1 | chr11:32438615 G>T | 5'Flank (SNP) | VAF 56/248 reads (23%) | called by muse, mutect2, varscan2
- ZFAND1 | c.-4A>T | 5'UTR (SNP) | VAF 9/63 reads (14%) | catalogued as rs1449779286; called by muse, mutect2, varscan2
- ZNF271P | n.2086C>G | RNA (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2, varscan2
